Somatic mutation profile of tumor specimen TARGET-10-PATWXC-09A (aliquot TARGET-10-PATWXC-09A-01D) from TARGET case TARGET-10-PATWXC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.0 years (5,488 days).
Specimen TARGET-10-PATWXC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bdff4756-107d-439e-9b29-8bb544062a1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATWXC-10A (Blood Derived Normal), aliquot TARGET-10-PATWXC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/27cc6cec-a84c-40ab-ba1e-4b40a77dc8a2

The open-access MAF lists 11 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, 5'UTR 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL11B | c.1294T>C p.C432R (on ENST00000357195 / NM_001282237.2; = p.C361R on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100595472, COSV61736189; called by muse, mutect2
- CCND3 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57828714; called by muse, mutect2, varscan2
- EGFLAM | c.2827G>T p.D943Y (on ENST00000354891 / NM_001205301.2; = p.D935Y on NM_152403.4) | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV59305524; called by muse, mutect2, varscan2
- IKZF5 | c.1232T>C p.F411S | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64397645; called by muse, mutect2, varscan2
- SCML4 | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV64636134; called by muse, mutect2, varscan2
- VNN3 | c.658C>A p.P220T | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC185 | c.1416C>T p.R472= | Silent (SNP) | VAF 18/28 reads (64%) | catalogued as rs1274621191, COSV64821197; called by muse, mutect2, varscan2
- MUC22 | c.4239T>C p.S1413= | Silent (SNP) | VAF 112/272 reads (41%) | called by muse, mutect2, varscan2
- SLC7A8 | c.1488C>T p.P496= | Silent (SNP) | VAF 38/80 reads (48%) | catalogued as rs756620184; called by muse, mutect2, varscan2
- KTI12 | c.-13G>A | 5'UTR (SNP) | VAF 6/11 reads (55%) | called by muse, mutect2, varscan2
- TRAV12-2 | chr14:21888502 ins GC | 3'Flank (INS) | VAF 10/35 reads (29%) | called by mutect2, pindel*, varscan2*
